Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8310, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8310-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Soft tissue, "peritumor fat," excision:
Benign adipose tissue with no neoplastic process identified.

B. Kidney, posterior margin #1, biopsy:
No tumor identified.
Permanent sections confirm the frozen section diagnosis.

C. Kidney, right, partial nephrectomy:

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, papillary subtype.
2. Tumor site: Right kidney.
3. Tumor focality: Unifocal.
4. Tumor size: 4.0 cm in greatest dimension.
5. Macroscopic extent of tumor: Tumor limited to kidney.
6. Microscopic extent of tumor: Foci of transgression of renal capsule.
7. Nuclear grade: Fuhrman grade 2/4.
8. Lymphovascular space invasion: Not identified.
9. Sarcomatoid features: Not identified.

Surgical Margin Status:

1. Tumor not identified at surgical margin.
2. Tumor present at inked capsular surface.

Lymph Node Status:

1. No lymph nodes submitted for evaluation.

Other:

1. pTNM stage: T3a.

COMMENTS:

The renal neoplasm predominantly has a papillary architecture with areas of interstitial macrophages. Foci of clear cell change are present. The lesion is felt to have an overall appearance of a papillary renal cell carcinoma.

This case was reviewed by [REDACTED] who agrees with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Peritumor fat
- B. Posterior margin #1 with frozen section
- C. Right renal tumor

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled with the patient's name,

Container A is additionally labeled "peri tumor fat" and contains two yellow-tan fibrofatty soft tissues, 1.1 x 0.7 x 0.4 cm and 2.0 x 1.0 x 0.4 cm. No nodules or lesions are identified. The specimen is entirely submitted in cassette A labeled

Container B is additionally labeled "Posterior margin #1" and contains two pink-tan soft tissues, each measuring 0.3 cm in greatest dimension. These

[page 2 of 2]
issues are entirely submitted for frozen section with the residual wrapped in tissue paper and entirely resubmitted for permanent section in cassette B labeled

Container C is additionally labeled "right renal tumor" and contains a 3.0 x 2.5 x 2.5 cm, partly fragmented partial nephrectomy specimen. The deep margin is remarkable for pink-tan normal appearing renal parenchyma which is grossly uninvolved with tumor. The remainder of the specimen is partially encapsulated by pink-gray, glistening renal capsule and Gerota's fascia. Partly extruded tan-orange tumor is identified, 4.0 x 2.5 x 2.5 cm in greatest dimension. This tumor abuts the inked capsule and to within 0.7 cm of the parenchymal margin. No additional lesions are identified. The specimen is entirely submitted in cassettes C1-7 labeled [REDACTED] designated as follows: C1-4 mass to inked parenchymal margin and capsule, perpendicular; 5-7 tumor. Additionally, a yellow, green and blue cassette are submitted for genomics research, each labeled [REDACTED]

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS PART B: No tumor identified on frozen section per [REDACTED]

Source: NCI Genomic Data Commons file 05cc4095-1560-4b42-955b-f09094e57c3f (TCGA-A4-8310.B8D23ED4-5903-4263-B380-4D492CCBACCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).